Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A39I, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A39I-01A (Primary Tumor).

		9/14/11

SPECIMEN TAKEN:

FINAL DIAGNOSIS ----- 1.

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Right lobe

HISTOLOGIC TYPE:

Papillary carcinoma, follicular variant

TUMOR SIZE:

Greatest dimension - 1.9 cm

FOCALITY:

Unifocal

LYMPH NODES:

None submitted

EXTENT OF INVASION

PRIMARY TUMOR:

pT1: Tumor size <2 cm, limited to thyroid

REGIONAL LYMPH NODES:

pNx: Cannot be assessed

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins are uninvolved

Distance of invasive carcinoma from nearest margin: 1 mm

Specify margin: Right anterior

VENOUS/LYMPHATIC INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS:

Nodular hyperplasia

Small solid cell nest (2 mm)

Single attached histologically unremarkable parathyroid, right lobe

2. LEFT INFERIOR PARA (EXCISION): PARATHYROID TISSUE (160 MG), WITH ATTACHED HISTOLOGICALLY UNREMARKABLE THYROID.

Source: NCI Genomic Data Commons file 8e6ec431-fde0-4701-af4a-3c8872b153c3 (TCGA-ET-A39I.130DFC95-3FA7-4B7B-9CC9-22C06F89C9A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).